Somatic mutation profile of tumor specimen 0DP6HV from CCDI case PBCCVP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 11.5 years (4,197 days).
Specimen 0DP6HV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e89d36d-b9a0-405d-ab61-dab3cf01aef5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a53f3e7-841a-4592-a17c-6c05b7414774

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.12745+1G>A p.X4249_splice (on ENST00000409039; = p.X4188_splice on NM_207437.3) | Splice Site (SNP) | VAF 94/351 reads (27%) | catalogued as COSV53020821; called by muse, varscan2
- HGS | c.1815C>T p.H605= | Silent (SNP) | VAF 121/524 reads (23%) | catalogued as rs182706220; called by muse, varscan2
- KRTAP4-4 | c.-37C>A | 5'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as rs1316552313; called by muse, varscan2
